Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3AJ, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3AJ-01A (Primary Tumor).

[page 1 of 3]
105-0-3
carcinoma, papillary, follicular variant 834013
Site: thyroid, NOS 273.9 LW 10/21/11

Page 1 of 3

Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender:

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) received

1. Nck: left central compartment
2. Thyroid: Total thyroid & Rt. central compartment stitch left superior pole

Diagnosis

1. Metastatic papillary thyroid carcinoma: Lymph nodes, 4 (left central compartment) neck dissection specimen
2. Multifocal papillary carcinoma, dominant follicular variant, 4.1 cm, right; with a classical papillary microcarcinoma with focal hobnail cell change involving surgical margins, 0.9 cm, left; and severe chronic lymphocytic thyroiditis: Thyroid
No pathological diagnosis: Lymph node, left perithyroidal
No pathological diagnosis: Lymph nodes, 9, isthmus
No pathological diagnosis: Lymph nodes, 10, right
- Total thyroidectomy and right central compartment specimen

Comment

The second dominant tumor measures 0.9 cm in the left lobe and it exhibits an invasive growth pattern with focal hobnail cell change and abuts focally the painted surgical margins. Since the surgical margins are involved by tumor and no extrathyroidal tissue is included in this specimen, evaluation of extrathyroidal extension cannot be reliably performed on this specimen.

Synoptic Data

Procedure:	Total thyroidectomy with central compartment dissection
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe: 6.2 cm 4.9 cm 3.2 cm Left lobe: 4.2 cm 3.0 cm

Criteria	Yes	NA

[page 2 of 3]
1.3 cm
Isthmus +/- pyramidal lobe:
5.5 cm
2.0 cm
1.0 cm
Central compartment:
2.5 cm
2.0 cm
0.5 cm
Specimen Weight: 53.7 g
Tumor Focality: Multifocal, bilateral
----- DOMINANT TUMOR -----
Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 4.1 cm
Additional dimension: 4.0 cm
Additional dimension: 2.8 cm
Histologic Type: Papillary carcinoma, follicular variant *per TSS, follicular variant = 100%*
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Distance of invasive carcinoma to closest margin: 1.0 mm
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present, extent widely invasive
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
----- SECOND TUMOR -----
Tumor Laterality: Left lobe
Tumor Size: Greatest dimension: 0.9 cm
Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, other: with focal hobnail cell change
Classical (papillary) architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margin(s) involved by carcinoma
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present, extent minimal
Lymph-Vascular Invasion: Indeterminate
Perineural Invasion: Not identified
Extrathyroidal Extension: Cannot be assessed
TNM Descriptors: m (multiple primary tumors)
Primary Tumor (pT): pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)
Regional Lymph Nodes (pN): pN1a: Nodal metastases to Level VI (pretracheal, paratracheal and prelaryngeal/Delphian) lymph nodes
Number of regional lymph nodes examined: 24
Number of regional lymph nodes involved: 4
Lymph Node, Extranodal Extension Not identified
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Thyroiditis, advanced
Other: additional papillary microcarcinoma, 0.1 cm, left lobe

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

MD

Electronically verified by:
MD

[page 3 of 3]
Clinical History

Thyroid ca

Gross Description

1. The specimen labeled with the patient's name and as "Neck: Left central compartment" consists of a piece of yellow-tan tissue that measures 3.0 x 1.2 x 0.8 cm.

1A bisected and submitted in toto

2. The specimen labeled with the patient's name and as "Thyroid: Total thyroid and right central compartment stitch left superior pole" consists of a thyroid gland that is oriented with a stitch and weighs 53.7 g. The right lobe measures 6.2 cm SI x 4.9 cm ML x 3.2 cm AP, the left lobe measures 4.2 cm SI x 3.0 cm ML x 1.3 cm AP and the isthmus measures 5.5 cm SI x 2.0 cm ML x 1.0 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands are identified grossly. There is a piece of fatty tissue at the inferior aspect of the right lobe measuring 2.0 x 2.5 x 0.5 cm. Multiple lymph nodes are identified from the soft tissue ranging in size from 0.4 to 1.2 cm. The right lobe contains a well delineated solid nodule that measures 4.1 cm SI x 4.0 cm ML x 2.8 cm AP. The upper mid pole of the left lobe contains a well delineated nodule measuring 0.9 cm SI x 0.7 cm ML x 0.6 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of right and left lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

2A-T right lobe, superior to inferior

2U-X isthmus

2Y-AD left lobe, superior to inferior

2AE-AF multiple lymph nodes each block

Source: NCI Genomic Data Commons file bca2ad84-be3f-4d06-a1c3-2021c3921e04 (TCGA-EM-A3AJ.1F3348F1-27A7-423E-8E8B-243921DC83A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).